Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAL4, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAL4-01A (Primary Tumor).

Concerning

Summary pathology report

Right orchidectomy; nonseminoma (MT + IT 50%, EC 40%, YST 10%, trophoblastic giant cells); diameter 3.5 cm; no angio-invasion; invasion of rete testis present; tumor confined to testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD-O-3
Mixed germ cell tumor
9685/3
Date @ Testis NOS
C629
QJ 3/5/14

Source: NCI Genomic Data Commons file 156f7880-8d1b-482d-a4f4-a8530cf895f8 (TCGA-2G-AAL4-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).